Somatic mutation profile of tumor specimen TCGA-D1-A15W-01A (aliquot TCGA-D1-A15W-01A-11D-A122-09) from TCGA case TCGA-D1-A15W, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 59.0 years (21,545 days).
Specimen TCGA-D1-A15W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4e006c5-640d-4741-b25f-8254bbea728f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A15W-10A (Blood Derived Normal), aliquot TCGA-D1-A15W-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b69e1022-b082-46c3-93d2-d66175f6a50c

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, In Frame Del 3, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs63749794, CM043245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 46/152 reads (30%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 100/331 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1698_1710delinsA p.K567_L570del (on ENST00000521381 / NM_181523.3; = p.K297_L300del on NM_181504.4) | In Frame Del (DEL) | VAF 86/340 reads (25%) | hotspot (GDC flag); called by pindel, varscan2*
- PTEN | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 67/180 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as CM981666, COSV64291076, COSV64292219, COSV64299142; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 108/304 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 100/300 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1360469415, COSV65077298; called by muse, mutect2, varscan2
- AGAP2 | c.1222C>A p.R408S (on ENST00000547588 / NM_001122772.2; = p.R72S on NM_014770.4) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs748818725, COSV57727366, COSV57729456; called by muse, mutect2, varscan2
- ARL8B | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV56578649; called by muse, mutect2, varscan2
- BOLL | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV56575208; called by muse, mutect2, varscan2
- BRF1 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as COSV59270405; called by muse, mutect2, varscan2
- CGA | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs745838602, COSV63644608; called by muse, mutect2, varscan2
- COL19A1 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59570355; called by muse, mutect2, varscan2
- CSMD3 | c.2518C>T p.P840S (on ENST00000297405 / NM_001363185.1; = p.P736S on NM_052900.3) | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770956958, COSV52225394; called by muse, mutect2, varscan2
- DNAH5 | c.8765G>A p.R2922H | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148539877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP3 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs200657045, COSV57857081; called by muse, mutect2, varscan2
- EGFR | c.2750G>C p.G917A | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV51815247; called by muse, mutect2
- EPRS1 | c.2048C>G p.P683R | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65099944; called by muse, mutect2, varscan2
- FASTKD1 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV70007004; called by muse, mutect2, varscan2
- KBTBD6 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65271556; called by muse, mutect2, varscan2
- KCNK10 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); catalogued as rs763733103, COSV56647485; called by muse, mutect2, varscan2
- KCTD8 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100759493, COSV63591325; called by muse, mutect2, varscan2
- KIF1A | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs545501989, COSV57493457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPAR6 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57313411; called by muse, mutect2, varscan2
- MAGEA3 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 125/343 reads (36%) | catalogued as rs782026359, COSV64755993; called by muse, mutect2, varscan2
- MAGEC1 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV53567688, COSV53575910; called by muse, mutect2, varscan2
- NRXN3 | c.335G>A p.R112H (on ENST00000557594 / NM_001272020.2; = p.R744H on NM_004796.6) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1265485518, COSV55317985; called by muse, mutect2, varscan2
- PCDH1 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs753105427, COSV54615871; called by muse, mutect2, varscan2
- PCDHA11 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV56513165; called by muse, mutect2, varscan2
- PKHD1 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV61882934; called by muse, mutect2, varscan2
- POLR3B | c.2933G>T p.R978L | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV57280942; called by muse, mutect2, varscan2
- PRDM10 | c.3469A>G p.I1157V | Missense Mutation (SNP) | VAF 153/548 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1269453027, COSV58802408; called by muse, mutect2
- PRPF8 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59264706; called by muse, mutect2, varscan2
- RARG | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58433492; called by muse, mutect2, varscan2
- RBL2 | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150272534; called by muse, mutect2, varscan2
- RIMS2 | c.4292G>A p.R1431H (on ENST00000666250 / NM_001348490.2; = p.R1002H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252961103, COSV51655841, COSV51695249; called by muse, mutect2, varscan2
- RUNDC3B | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs894657061, COSV56694545; called by muse, mutect2, varscan2
- SAMD3 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100696459, COSV62386959; called by muse, varscan2
- SCAF4 | c.2735A>G p.H912R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.084); catalogued as rs1255176381, COSV54256588; called by muse, mutect2, varscan2
- SCN2A | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 103/312 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51846350; called by muse, mutect2, varscan2
- SEC16A | c.4601C>T p.A1534V | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751988588, COSV51531919; called by muse, mutect2, varscan2
- SKP2 | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57042974; called by muse, mutect2, varscan2
- SLC17A9 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs780048387, COSV64847601; called by muse, mutect2, varscan2
- SMC5 | c.1672A>T p.K558* | Nonsense Mutation (SNP) | VAF 53/173 reads (31%) | catalogued as COSV63193779; called by muse, mutect2, varscan2
- SNTG1 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52453640; called by muse, varscan2
- STAB2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 127/410 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs199583404; called by muse, mutect2, varscan2
- TBC1D2 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs369619412, COSV59786021; called by muse, mutect2, varscan2
- TENM3 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV69312342; called by muse, mutect2, varscan2
- VPS13D | c.8687C>T p.T2896M | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367962618; called by muse, mutect2, varscan2
- WDR49 | c.1634C>A p.S545Y (on ENST00000308378 / NM_001366158.1; = p.S886Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1353172675, COSV57706545, COSV57711317; called by muse, mutect2, varscan2
- ZMYM3 | c.1831G>C p.V611L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV58738870; called by muse, mutect2, varscan2
- ACAP2 | c.1066_1083del p.V356_A361del | In Frame Del (DEL) | VAF 45/187 reads (24%) | called by mutect2, pindel, varscan2
- ARID1A | c.6024_6026del p.L2009del | In Frame Del (DEL) | VAF 90/222 reads (41%) | called by pindel, varscan2
- CFH | c.3216_3217del p.R1072Sfs*6 | Frame Shift Del (DEL) | VAF 150/841 reads (18%) | called by pindel, varscan2
- DEGS1 | c.759del p.F254Sfs*23 | Frame Shift Del (DEL) | VAF 35/170 reads (21%) | called by mutect2, pindel, varscan2
- DUSP14 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2
- GCC1 | c.1690del p.R564Gfs*16 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- ADAMTS5 | c.1209C>T p.H403= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs774940785, COSV53176232, COSV99034717; called by muse, mutect2, varscan2
- CD200R1 | c.423C>T p.F141= (on ENST00000471858 / NM_170780.3; = p.F164= on NM_138806.4) | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as COSV55601797; called by muse, mutect2
- CEP250 | c.2217G>A p.A739= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1462149509, COSV61169618; called by muse, mutect2, varscan2
- CHD8 | c.6705G>A p.A2235= (on ENST00000646647 / NM_001170629.2; = p.A1956= on NM_020920.4) | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs1318397540, COSV63037076; called by muse, mutect2, varscan2
- ERCC3 | c.51G>A p.R17= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV53428051; called by muse, mutect2, varscan2
- GSTCD | c.1761C>T p.L587= (on ENST00000360505 / NM_001031720.3; = p.L500= on NM_024751.3) | Silent (SNP) | VAF 109/357 reads (31%) | catalogued as rs1314704203, COSV64734147; called by muse, mutect2, varscan2
- HNRNPL | c.285G>A p.P95= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as rs1313405735, COSV55492469; called by muse, mutect2, varscan2
- LRRC30 | c.603C>T p.I201= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs202241153, COSV67301591; called by muse, mutect2, varscan2
- NOD1 | c.2583G>A p.A861= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs760276479, COSV56113355; called by muse, mutect2, varscan2
- OR5P3 | c.231C>A p.V77= | Silent (SNP) | VAF 54/155 reads (35%) | catalogued as COSV60429502; called by muse, mutect2, varscan2
- SLC17A3 | c.51A>G p.A17= | Silent (SNP) | VAF 99/314 reads (32%) | catalogued as COSV57760586; called by muse, mutect2, varscan2
- TYK2 | c.2823C>G p.R941= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV53388780; called by muse, mutect2, varscan2
- ZC3H11A | c.1383T>C p.G461= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV59747749; called by muse, mutect2, varscan2
- CTBP2 | c.58+11720C>T | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as rs148416442; called by muse, mutect2, varscan2
